Gene-level copy-number profile of specimen HCM-CSHL-0434-C24-85A from HCMI case HCM-CSHL-0434-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,282 days).
Specimen HCM-CSHL-0434-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 41c87996-44a0-4a20-b95e-7a714efef4b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0434-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/14aa51a0-de39-4647-b6b6-94fbf6289b68

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 659; copy number 2: 14,067; copy number 3: 24,780; copy number 4: 15,272; copy number 5: 2,996; copy number 6: 326; copy number 7: 554; copy number 8: 34; copy number 10: 8; copy number 11: 59; copy number 12: 5; copy number 13: 95; copy number 17: 14; copy number 20: 4; copy number 21: 31; copy number 22: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 809 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:58,275,532–69,674,349, 210 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:101,362,875–101,559,024, 1 gene, copy number 7 (within-gene range 5–7): COL26A1.
- chr7:101,562,779–117,230,176, 238 genes, copy number 7–13 (within-gene range 2–13) (broad region; genes not listed).
- chr7:117,184,126–120,227,213, 27 genes, copy number 13: AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2.
- chr14:32,934,396–33,804,176, 3 genes, copy number 8: NPAS3, AL161851.1, AL161851.2.
- chr14:36,070,427–36,176,468, 2 genes, copy number 7: LINC00609, PTCSC3.
- chr14:50,975,262–59,371,405, 164 genes, copy number 7 (broad region; genes not listed).
- chr19:29,489,775–29,824,312, 7 genes, copy number 11–13 (within-gene range 5–13): AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1.
- chr19:33,067,175–33,067,433, 1 gene, copy number 10: AC008521.2.
- chr19:34,126,973–34,127,423, 1 gene, copy number 7: CHCHD2P3.
- chr19:34,837,889–35,625,355, 57 genes, copy number 7–11: AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG, CD22, U62631.1, MIR5196, FFAR1, FFAR3, GPR42, EEF1A1P7, LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, LINC01766, AC002115.1, HAUS5.
- chr19:39,083,913–40,808,434, 98 genes, copy number 8–22 (within-gene range 6–22) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 659. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
